Somatic mutation profile of tumor specimen TCGA-VS-A9U7-01A (aliquot TCGA-VS-A9U7-01A-11D-A42O-09) from TCGA case TCGA-VS-A9U7, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 30.7 years (11,210 days).
Specimen TCGA-VS-A9U7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8f24fdc-1da1-4334-ac15-965b06752a7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9U7-10A (Blood Derived Normal), aliquot TCGA-VS-A9U7-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cc0344c-2064-4f04-a259-c090e52bb365

The open-access MAF lists 180 somatic variants for this specimen: 124 protein-altering or splice-affecting, 49 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 49, Nonsense Mutation 11, Intron 2, RNA 2, 5'Flank 2, Frame Shift Del 2, Splice Region 1, Translation Start Site 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAGAB | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV99972004; called by muse, mutect2, varscan2
- ABLIM1 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs868447773, COSV99522012, COSV99522456; called by muse, mutect2, varscan2
- ADAM9 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV101122269; called by muse, mutect2, varscan2
- ADPRH | c.354G>A p.W118* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100813353; called by muse, mutect2, varscan2
- AFF3 | c.2056G>C p.E686Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100419707; called by muse, mutect2, varscan2
- ALPK2 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.177); catalogued as COSV100864610; called by muse, mutect2, varscan2
- ANKS1A | c.2449C>T p.Q817* | Nonsense Mutation (SNP) | VAF 23/30 reads (77%) | catalogued as rs1161375894, COSV100832700; called by muse, mutect2, varscan2
- ANXA10 | c.356G>C p.R119T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV63738624; called by muse, mutect2, varscan2
- AOX1 | c.771C>G p.F257L | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV101022168; called by muse, mutect2, varscan2
- ARHGEF5 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as rs756540378, COSV99283051; called by muse, mutect2, varscan2
- ARSF | c.682C>G p.L228V | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV100839562; called by muse, mutect2, varscan2
- ASH1L | c.5002G>A p.D1668N | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as rs1229275102, COSV100853539; called by muse, mutect2, varscan2
- BAIAP2 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100348565; called by muse, mutect2, varscan2
- BCOR | c.3421G>A p.D1141N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100653658; called by muse, mutect2, varscan2
- BRCA1 | c.2666C>G p.S889C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58801122; called by muse, mutect2, varscan2
- C12orf40 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV100210492; called by muse, mutect2, varscan2
- C14orf180 | c.31G>C p.D11H | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as COSV100118797; called by muse, mutect2, varscan2
- CAMK2G | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99990078; called by muse, mutect2, varscan2
- CCDC39 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99870115; called by muse, mutect2, varscan2
- CCDC66 | c.1591G>A p.E531K (on ENST00000394672 / NM_001353147.1; = p.E497K on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.181); catalogued as COSV100413816, COSV100414172; called by muse, mutect2, varscan2
- CCDC66 | c.1681G>A p.D561N (on ENST00000394672 / NM_001353147.1; = p.D527N on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100414178; called by muse, mutect2, varscan2
- CDKN3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/86 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as COSV99369930; called by muse, mutect2, varscan2
- CELSR1 | c.2618C>G p.S873* | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | catalogued as COSV99419243; called by muse, mutect2, varscan2
- COL7A1 | c.2798G>A p.R933K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV100097047; called by muse, mutect2, varscan2
- CSGALNACT1 | c.588G>C p.E196D | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV100175343; called by muse, mutect2, varscan2
- CST2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.973); catalogued as rs372139444, COSV59031682; called by muse, mutect2, varscan2
- CUL1 | c.2157G>C p.M719I | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100296825; called by muse, mutect2, varscan2
- CUL4B | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.094); catalogued as COSV100340919, COSV60684215; called by muse, mutect2, varscan2
- DCLK3 | c.120G>T p.R40S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV101374051; called by muse, mutect2, varscan2
- DIAPH1 | c.2035C>A p.P679T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.329); catalogued as COSV99526965; called by muse, mutect2, varscan2
- DISP3 | c.2287G>C p.D763H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99609462; called by muse, mutect2, varscan2
- DLGAP3 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1263276619, COSV99332983; called by muse, mutect2, varscan2
- DNAJC15 | c.68C>A p.S23* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as COSV101004960, COSV64871757; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.737G>A p.W246* | Nonsense Mutation (SNP) | VAF 27/124 reads (22%) | catalogued as COSV100668754; called by muse, mutect2, varscan2
- EPC1 | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.708); catalogued as COSV53926848, COSV99553266; called by muse, mutect2, varscan2
- EPHA6 | c.1945G>A p.A649T (on ENST00000389672 / NM_001080448.3; = p.A41T on NM_173655.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1323884785, COSV67575443; called by muse, mutect2, varscan2
- EPHB4 | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.05); catalogued as COSV100639588, COSV62269519; called by muse, mutect2, varscan2
- ERBIN | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1166590738, COSV52319435, COSV99397493; called by muse, mutect2, varscan2
- ERCC6 | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV100876063; called by muse, mutect2, varscan2
- ERP44 | c.677C>G p.A226G | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99316566; called by muse, mutect2, varscan2
- F13B | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as COSV100803363; called by muse, mutect2, varscan2
- FAM13B | c.354G>C p.L118F | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV99221628; called by muse, mutect2, varscan2
- FAM227B | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs919837777, COSV100175392; called by muse, mutect2, varscan2
- FANCB | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 38/108 reads (35%) | catalogued as COSV100146639; called by muse, mutect2, varscan2
- FBRS | c.319G>A p.D107N (on ENST00000287468; = p.D627N on NM_001105079.3) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV99789265; called by muse, mutect2, varscan2
- GBP6 | c.730G>C p.D244H | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV100969617, COSV65011756; called by muse, mutect2, varscan2
- GSTA1 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100575582, COSV58015397; called by muse, mutect2, varscan2
- GUSB | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.124); catalogued as COSV100512710; called by muse, mutect2
- HAP1 | c.1786G>C p.E596Q (on ENST00000310778 / NM_001367460.1; = p.E544Q on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as rs555784831, COSV100169874, COSV57877777, COSV57878265; called by muse, mutect2, varscan2
- HELQ | c.1230C>G p.F410L | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99787416, COSV99787958; called by muse, mutect2, varscan2
- HERC1 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as COSV101496283; called by muse, mutect2, varscan2
- HOXD13 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV101184316; called by muse, mutect2, varscan2
- HTT | c.2789C>T p.S930L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV100751061; called by muse, varscan2
- IGF1R | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.15); PolyPhen benign (0.267); catalogued as COSV99156471; called by muse, mutect2, varscan2
- IRAK4 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.17); PolyPhen benign (0.181); catalogued as COSV101471836; called by muse, mutect2, varscan2
- KAT8 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV99571679; called by muse, mutect2, varscan2
- KIF18B | c.1905G>C p.L635F (on ENST00000593135 / NM_001265577.2; = p.L647F on NM_001264573.2) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.264); catalogued as COSV100192436; called by muse, mutect2, varscan2
- KMT2B | c.6001G>A p.E2001K | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as COSV99720208; called by muse, mutect2, varscan2
- KMT2B | c.6319G>A p.E2107K | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as COSV99720212; called by muse, mutect2, varscan2
- LDB2 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100454327; called by muse, mutect2, varscan2
- LY6H | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV99048101; called by muse, mutect2, varscan2
- MCCC1 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV99659955; called by muse, mutect2, varscan2
- MCCC2 | c.1412C>G p.S471* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100040458; called by muse, mutect2, varscan2
- MMP3 | c.1239G>C p.E413D | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV100242932; called by muse, mutect2, varscan2
- MSL2 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1394652093, COSV99387823; called by muse, mutect2, varscan2
- MUC15 | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV99846562; called by muse, mutect2, varscan2
- MYO7A | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.186); catalogued as COSV101289221, COSV68684878; called by muse, mutect2, varscan2
- NAA16 | c.10G>T p.V4L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.011); catalogued as COSV101038394; called by muse, mutect2, varscan2
- NAA30 | c.1006C>T p.L336F | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100035950; called by muse, mutect2
- NCOA7 | c.2747C>G p.S916C | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as COSV57658011; called by muse, mutect2, varscan2
- NIFK | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.565); catalogued as rs756299604, COSV99590733; called by muse, mutect2, varscan2
- NOL6 | c.2369G>C p.G790A | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99954989; called by muse, mutect2, varscan2
- NPR2 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61309784; called by muse, mutect2, varscan2
- OR4F15 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV100173928; called by muse, mutect2, varscan2
- OTOA | c.3184G>A p.E1062K (on ENST00000286149; = p.E1048K on NM_144672.4) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV53765566; called by mutect2, varscan2
- PAK6 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99544802; called by muse, mutect2, varscan2
- PCM1 | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as COSV61517530; called by muse, mutect2, varscan2
- PDLIM5 | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100524121; called by muse, mutect2, varscan2
- PDS5A | c.2584C>T p.R862W | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57825411; called by muse, mutect2, varscan2
- PDZD8 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV100559586; called by muse, mutect2, varscan2
- PEAK1 | c.4315G>A p.E1439K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.013); catalogued as COSV100433292; called by muse, mutect2, varscan2
- PGBD1 | c.835G>C p.E279Q | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV99460663; called by muse, mutect2, varscan2
- PIGA | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs774644659, COSV61238188; called by muse, mutect2, varscan2
- PLPP7 | c.438G>C p.M146I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100952596; called by muse, mutect2
- PLXNA1 | c.1778C>T p.S593L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs758044637, COSV52530844, COSV99303959; called by muse, mutect2, varscan2
- PRKDC | c.9409G>A p.E3137K | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100040773, COSV100041884; called by muse, mutect2, varscan2
- PROP1 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100383749; called by muse, mutect2, varscan2
- PSTPIP1 | c.269C>G p.S90* | Nonsense Mutation (SNP) | VAF 28/54 reads (52%) | catalogued as COSV99143839; called by muse, mutect2, varscan2
- RAB2B | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99398475; called by muse, mutect2
- RBM47 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs763314452, COSV99920360; called by muse, mutect2
- RETREG3 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV58703724; called by muse, mutect2, varscan2
- RIPPLY3 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100289391; called by muse, mutect2, varscan2
- RPP25 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1203943359, COSV100446242; called by muse, mutect2, varscan2
- RUFY2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV61192611; called by muse, mutect2, varscan2
- RYR3 | c.4944G>C p.K1648N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); catalogued as COSV101213397; called by muse, mutect2
- SAMD4A | c.2129-1G>C p.X710_splice | Splice Site (SNP) | VAF 13/28 reads (46%) | catalogued as COSV99200766; called by muse, mutect2, varscan2
- SCFD2 | c.461T>A p.F154Y | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV101189434, COSV66368986; called by muse, mutect2, varscan2
- SEMA3B | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs782593824, COSV57114562; called by muse, mutect2, varscan2
- SIGMAR1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV99449572; called by muse, mutect2, varscan2
- SLC10A1 | c.153C>G p.I51M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV99384442, COSV99384528; called by muse, mutect2, varscan2
- SLC16A12 | c.898C>G p.L300V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100370405; called by muse, mutect2, varscan2
- SLC16A13 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100338702; called by muse, mutect2, varscan2
- SLC22A11 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754364564, COSV100102552, COSV57252562; called by muse, mutect2, varscan2
- SLC22A11 | c.1483C>G p.L495V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); catalogued as COSV100102529; called by muse, mutect2, varscan2
- SLC25A20 | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV100033836; called by muse, mutect2, varscan2
- SLC2A2 | c.1545G>A p.M515I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV58585460, COSV58587216; called by muse, mutect2, varscan2
- SLC44A1 | c.1518C>G p.I506M | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100570572, COSV58264461; called by muse, mutect2, varscan2
- SLC4A10 | c.2044G>A p.E682K (on ENST00000446997 / NM_001354461.2; = p.E652K on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs376393572; called by muse, mutect2, varscan2
- SMARCA4 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1206010353, COSV100758939; called by muse, mutect2, varscan2
- SOCS6 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV101205815, COSV67546311; called by muse, mutect2, varscan2
- TBX22 | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 23/40 reads (58%) | catalogued as COSV100960891; called by muse, mutect2, varscan2
- TBX4 | c.825G>C p.M275I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV99540503; called by muse, mutect2, varscan2
- TP53I13 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs751335473, COSV56195787; called by muse, mutect2, varscan2
- TPM2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV100253407; called by muse, mutect2, varscan2
- TPM2 | c.372G>A p.E124= | Splice Region (SNP) | VAF 18/40 reads (45%) | catalogued as COSV100253410; called by muse, mutect2, varscan2
- TSHZ2 | c.2657C>G p.S886C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs753732895, COSV100296519; called by muse, mutect2, varscan2
- TSR1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs144223722; called by muse, mutect2, varscan2
- WIPF1 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV55820324; called by muse, mutect2, varscan2
- ZNF100 | c.1431G>A p.M477I | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs778689509, COSV59747546; called by muse, mutect2, varscan2
- ZNF334 | c.702G>T p.R234S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs769068262, COSV100749153; called by muse, mutect2, varscan2
- ZNF394 | c.100G>C p.D34H | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV100460315; called by muse, mutect2, varscan2
- JAG1 | c.3269_3278del p.Y1090Cfs*27 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- MYO1D | c.2795del p.F932Sfs*19 | Frame Shift Del (DEL) | VAF 37/96 reads (39%) | called by mutect2, pindel, varscan2
- TRAV19 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- ADCY2 | c.2985C>T p.F995= | Silent (SNP) | VAF 38/81 reads (47%) | catalogued as COSV100603481; called by muse, mutect2, varscan2
- AFF3 | c.2142C>T p.N714= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV57841742; called by muse, mutect2, varscan2
- AKAP10 | c.1215C>A p.I405= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- C1QTNF5 | c.318C>T p.F106= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100264740; called by muse, mutect2, varscan2
- CC2D1B | c.600G>A p.L200= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as COSV99430147; called by muse, mutect2, varscan2
- CCDC105 | c.888G>A p.A296= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs139591424; called by muse, mutect2, varscan2
- CDH10 | c.2025G>A p.L675= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs752893007, COSV100052436; called by muse, mutect2, varscan2
- CHD7 | c.3144G>A p.G1048= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV101418355; called by muse, mutect2, varscan2
- CNTFR | c.933G>C p.T311= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs747993586, COSV100667598, COSV63634756; called by muse, mutect2, varscan2
- COL17A1 | c.2925C>T p.G975= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV100793256; called by muse, mutect2, varscan2
- DNAJA4 | c.1053G>A p.Q351= (on ENST00000343789; = p.Q380= on NM_018602.3) | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99144613; called by muse, mutect2, varscan2
- DOK4 | c.63C>T p.L21= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs368155888, COSV100407623; called by muse, mutect2, varscan2
- F2RL2 | c.462C>T p.L154= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV56971295, COSV56971814, COSV99167780; called by muse, mutect2, varscan2
- GATB | c.51C>T p.F17= | Silent (SNP) | VAF 56/130 reads (43%) | catalogued as rs757217781, COSV56129302, COSV56131138; called by muse, mutect2, varscan2
- GLE1 | c.774C>T p.L258= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1205948429, COSV100012726; called by muse, mutect2, varscan2
- HGD | c.837G>A p.L279= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs773158062, COSV99381253; called by muse, mutect2, varscan2
- LRRC30 | c.339G>T p.V113= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV101274434; called by muse, mutect2, varscan2
- MAN2B2 | c.2976C>T p.I992= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV99577806; called by muse, mutect2, varscan2
- MTTP | c.189G>T p.V63= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV55508501, COSV99645434; called by muse, mutect2, varscan2
- MUC3A | c.7239C>T p.I2413= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs753838319; called by muse, mutect2, varscan2
- MYH4 | c.249C>G p.P83= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV99701852; called by muse, mutect2, varscan2
- NONO | c.591G>A p.G197= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs1303322565, COSV52136652, COSV99339030; called by muse, mutect2, varscan2
- NYAP1 | c.864G>A p.P288= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs751615498, COSV55718270, COSV55720519; called by muse, mutect2, varscan2
- OR1E1 | c.678C>G p.L226= | Silent (SNP) | VAF 42/124 reads (34%) | catalogued as COSV100491983; called by muse, mutect2, varscan2
- OR1L4 | c.627G>A p.V209= | Silent (SNP) | VAF 6/79 reads (8%) | catalogued as COSV99413923; called by muse, mutect2
- PAPLN | c.639C>T p.I213= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs745758400, COSV99390126; called by muse, varscan2
- PDE6B | c.2283G>A p.R761= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as rs754273223, COSV99728097; called by muse, mutect2, varscan2
- PEX26 | c.36C>T p.L12= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs765484850, COSV100299132; called by muse, mutect2, varscan2
- POLR3A | c.3801C>T p.I1267= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100965762, COSV64931520; called by muse, mutect2, varscan2
- PTK2B | c.1878C>T p.F626= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100594248; called by muse, mutect2, varscan2
- RANBP2 | c.543G>A p.L181= | Silent (SNP) | VAF 131/343 reads (38%) | catalogued as rs146460580; ClinVar: likely benign; called by muse, mutect2, varscan2
- RASA2 | c.1818G>C p.L606= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV99656546; called by muse, mutect2, varscan2
- SFSWAP | c.2688G>A p.E896= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV99906277; called by muse, mutect2, varscan2
- SIRT1 | c.2199G>A p.V733= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV53019622; called by muse, mutect2, varscan2
- SMTNL2 | c.1347C>T p.Y449= (on ENST00000389313 / NM_001114974.2; = p.Y305= on NM_198501.3) | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as rs140620311; called by muse, mutect2, varscan2
- SORL1 | c.1920G>A p.G640= | Silent (SNP) | VAF 22/29 reads (76%) | catalogued as COSV99494823; called by muse, mutect2, varscan2
- SUSD1 | c.630C>T p.F210= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV100813427; called by muse, mutect2, varscan2
- TBC1D26 | c.519C>T p.I173= | Silent (SNP) | VAF 38/77 reads (49%) | catalogued as rs752084919, COSV101343680; called by muse, mutect2, varscan2
- TMEM132D | c.1761G>A p.A587= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs150169563; called by muse, mutect2, varscan2
- TMEM176B | c.435C>G p.L145= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV100423636; called by muse, mutect2, varscan2
- TMPRSS6 | c.1260G>A p.G420= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as COSV100696036; called by muse, mutect2, varscan2
- TOP3A | c.1524G>A p.V508= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100329226; called by muse, mutect2
- TP73 | c.1785C>T p.T595= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs1294981679, COSV100601487; called by muse, mutect2, varscan2
- TRANK1 | c.2436G>A p.K812= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV57146344; called by muse, mutect2, varscan2
- TRMT1L | c.1083G>A p.L361= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV100834696; called by muse, mutect2, varscan2
- TTN | c.10611C>T p.F3537= (on ENST00000591111; = p.F3491= on NM_003319.4) | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100622735; called by muse, mutect2, varscan2
- UMODL1 | c.3015C>T p.R1005= (on ENST00000408910 / NM_001004416.2; = p.R1133= on NM_173568.3) | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV101252651; called by muse, mutect2, varscan2
- ZMYM1 | c.978G>A p.V326= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100721027; called by muse, mutect2, varscan2
- ZXDA | c.1489C>T p.L497= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV100699444; called by muse, mutect2, varscan2
- AL136982.4 | n.748G>A | RNA (SNP) | VAF 84/238 reads (35%) | called by muse, mutect2
- AP000769.3 | chr11:65502445 G>T | 5'Flank (SNP) | VAF 26/69 reads (38%) | catalogued as rs753523012; called by muse, varscan2
- AP000769.3 | chr11:65502606 G>C | 5'Flank (SNP) | VAF 25/65 reads (38%) | catalogued as rs920080166; called by muse, mutect2, varscan2
- CORO6 | c.-76C>T | 5'UTR (SNP) | VAF 20/49 reads (41%) | catalogued as rs1256684903, COSV99282639; called by muse, mutect2, varscan2
- LRRFIP1 | c.249+12976C>T | Intron (SNP) | VAF 14/22 reads (64%) | catalogued as rs542761172, COSV99791060; called by muse, mutect2, varscan2
- PMS2P3 | n.475C>G | RNA (SNP) | VAF 29/104 reads (28%) | catalogued as rs1356904237; called by muse, mutect2, varscan2
- PRMT8 | c.76-1945C>T | Intron (SNP) | VAF 7/10 reads (70%) | catalogued as rs768588074, COSV99713560; called by muse, mutect2, varscan2
